Somatic mutation profile of tumor specimen TARGET-30-PARUTX-01A (aliquot TARGET-30-PARUTX-01A-01D) from TARGET case TARGET-30-PARUTX, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 1.0 years (381 days).
Specimen TARGET-30-PARUTX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed0d6051-f9cc-43ee-b0e5-1b6311372965.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARUTX-10A (Blood Derived Normal), aliquot TARGET-30-PARUTX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c09d5663-4882-438c-a7f6-8ecb04060c3b

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PHOX2B | c.317C>G p.T106S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV56928506, COSV99890965; called by muse, mutect2, varscan2
- XPO5 | c.2920+21G>T | Intron (SNP) | VAF 37/85 reads (44%) | catalogued as COSV54833644; called by muse, mutect2, varscan2
